Somatic mutation profile of tumor specimen TCGA-QG-A5Z2-01A (aliquot TCGA-QG-A5Z2-01A-11D-A28G-10) from TCGA case TCGA-QG-A5Z2, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage I; Age at diagnosis: 61.2 years (22,367 days).
Specimen TCGA-QG-A5Z2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 39a810b8-66e7-4296-9f34-9f0201880595.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QG-A5Z2-10A (Blood Derived Normal), aliquot TCGA-QG-A5Z2-10A-01D-A28G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b35f2218-6749-4786-a324-ca6328d691a7

The open-access MAF lists 1,310 somatic variants for this specimen: 944 protein-altering or splice-affecting, 262 silent, 104 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 652, Silent 262, Frame Shift Del 184, Intron 43, Nonsense Mutation 41, 3'UTR 38, Frame Shift Ins 29, Splice Site 16, Splice Region 12, 5'UTR 12, In Frame Del 9, 3'Flank 4.

Variants (750 of 1,310; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1660C>T p.R554* | Nonsense Mutation (SNP) | VAF 66/209 reads (32%) | catalogued as rs137854573, CM920034, COSV57321615; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CEP290 | c.1666del p.I556Ffs*17 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | catalogued as rs727503855, CD073590; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- COL1A1 | c.1865del p.P622Lfs*144 | Frame Shift Del (DEL) | VAF 12/65 reads (18%) | catalogued as rs72651620, CD063487; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- FLAD1 | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs771466122, CM166319, COSV52695597; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GLB1 | c.245+1G>A p.X82_splice | Splice Site (SNP) | VAF 9/70 reads (13%) | catalogued as rs778423653, CS042814, COSV100257235; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HPS1 | c.972del p.M325Wfs*6 | Frame Shift Del (DEL) | VAF 7/36 reads (19%) | catalogued as rs281865082, CD982691; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2*
- LARP7 | c.1213del p.T405Qfs*5 | Frame Shift Del (DEL) | VAF 45/162 reads (28%) | catalogued as rs750946801; ClinVar: likely pathogenic; called by mutect2, varscan2
- LRPPRC | c.3147del p.A1051Hfs*6 | Frame Shift Del (DEL) | VAF 28/87 reads (32%) | catalogued as rs769022521; ClinVar: pathogenic; called by mutect2, varscan2
- NBAS | c.1501C>T p.R501* | Nonsense Mutation (SNP) | VAF 25/120 reads (21%) | catalogued as rs759960319, COSV55732598; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RAD50 | c.2801del p.N934Ifs*6 | Frame Shift Del (DEL) | VAF 22/86 reads (26%) | catalogued as rs748536322; ClinVar: pathogenic; called by mutect2, varscan2
- SLC19A3 | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121917882, CM051990, COSV51452421; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC25A1 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs431905510, CM131841, COSV99311045; ClinVar: pathogenic; called by muse, mutect2, varscan2
- STAT5B | c.1102dup p.Q368Pfs*9 | Frame Shift Ins (INS) | VAF 22/112 reads (20%) | catalogued as rs761761205; ClinVar: pathogenic; called by mutect2, varscan2
- TNNT2 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs397516465, CM1413538, COSV52665154; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TPP1 | c.1449del p.I484Sfs*4 | Frame Shift Del (DEL) | VAF 17/82 reads (21%) | catalogued as rs1057516264; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- AADACL4 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.76); PolyPhen benign (0.094); catalogued as rs775507000, COSV66105905; called by muse, mutect2, varscan2
- ABCA3 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV57054263; called by muse, mutect2, varscan2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 19/92 reads (21%) | catalogued as rs749943218; called by mutect2, varscan2
- AC090517.4 | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.998); catalogued as rs769699925; called by muse, mutect2, varscan2
- AC090517.4 | c.1783del p.S595Vfs*7 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as rs1157171684; called by mutect2, pindel
- AC092143.1 | c.1525C>T p.R509C | Missense Mutation (SNP) | VAF 60/226 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.115); catalogued as COSV59247382; called by muse, mutect2, varscan2
- ACTR3B | c.1092G>T p.E364D | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.81); PolyPhen benign (0.006); catalogued as COSV99060552; called by muse, mutect2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 42/67 reads (63%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM30 | c.844del p.S282Vfs*3 | Frame Shift Del (DEL) | VAF 7/45 reads (16%) | catalogued as rs757984494, COSV65561192; called by mutect2, pindel, varscan2
- ADAMTSL3 | c.1849G>A p.E617K | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as rs370221387, COSV54437015; called by muse, mutect2, varscan2
- ADCY4 | c.2951G>A p.R984Q | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs780875775; called by muse, mutect2, varscan2
- ADGB | c.4838G>A p.R1613Q | Missense Mutation (SNP) | VAF 92/312 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs754776474, COSV62235294; called by muse, mutect2, varscan2
- ADGRA3 | c.329+2T>C p.X110_splice | Splice Site (SNP) | VAF 53/181 reads (29%) | catalogued as COSV100529863; called by muse, mutect2, varscan2
- ADGRB1 | c.2869G>A p.V957M | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs775749064, COSV60092069; called by muse, mutect2, varscan2
- ADPRM | c.131A>G p.Y44C | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65755167; called by muse, mutect2, varscan2
- AFF1 | c.2484A>T p.R828S | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV57122828; called by muse, mutect2
- AGMO | c.914del p.G305Vfs*31 | Frame Shift Del (DEL) | VAF 9/51 reads (18%) | catalogued as COSV61124382; called by mutect2, pindel, varscan2
- AGTR1 | c.248T>C p.L83P | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV62559667; called by muse, mutect2, varscan2
- AK9 | c.3142A>G p.N1048D | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1312101709; called by muse, mutect2, varscan2
- AKNA | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.179); catalogued as rs552700642, COSV99801335; called by muse, mutect2, varscan2
- AKR1C3 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 11/147 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as rs782497370, COSV65911184; called by muse, mutect2
- AL592490.1 | c.1564A>G p.K522E | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.079); catalogued as COSV69425133, COSV69427014; called by muse, mutect2, varscan2
- ALG1 | c.764C>T p.T255M | Missense Mutation (SNP) | VAF 44/295 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs143906919; called by muse, mutect2, varscan2
- ALG11 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs200166628; called by muse, mutect2, varscan2
- ALOX12B | c.1163C>T p.A388V | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs202128350; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMT | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs369030035; called by muse, mutect2, varscan2
- ANAPC2 | c.802G>A p.V268M | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV59245294; called by muse, mutect2, varscan2
- ANKRD13B | c.391G>A p.V131M | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.418); catalogued as rs774030034, COSV67473645; called by muse, mutect2, varscan2
- ANXA6 | c.1808T>A p.F603Y | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.07); catalogued as COSV62907841; called by muse, mutect2, varscan2
- AP000812.4 | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as COSV99597668; called by muse, mutect2, varscan2
- AP1G2 | c.1092-1G>A p.X364_splice | Splice Site (SNP) | VAF 9/67 reads (13%) | catalogued as COSV99846163; called by muse, mutect2, varscan2
- APBA3 | c.1387G>A p.A463T | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.837); catalogued as rs575676926, COSV53661364; called by muse, mutect2
- APEH | c.1527del p.X509_splice | Splice Site (DEL) | VAF 14/125 reads (11%) | catalogued as rs1255876232; called by mutect2, pindel, varscan2
- APOBEC1 | c.208T>A p.F70I | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.025); catalogued as rs1555093510, COSV57549846; called by muse, mutect2, varscan2
- APOL1 | c.371T>C p.M124T | Missense Mutation (SNP) | VAF 34/396 reads (9%) | SIFT tolerated (0.69); PolyPhen benign (0.048); catalogued as rs773763181, COSV59869672; called by muse, mutect2
- ARHGAP17 | c.2440del p.Q814Nfs*23 (on ENST00000289968 / NM_001006634.3; = p.Q736Nfs*23 on NM_018054.6) | Frame Shift Del (DEL) | VAF 26/96 reads (27%) | catalogued as rs773922861; called by mutect2, pindel, varscan2
- ARHGAP33 | c.1885G>A p.V629I | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.023); catalogued as rs769754690; called by muse, mutect2, varscan2
- ARHGAP39 | c.1095del p.S366Rfs*18 | Frame Shift Del (DEL) | VAF 8/81 reads (10%) | catalogued as rs751388541; called by mutect2, pindel
- ARHGEF1 | c.1819C>T p.R607C | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs782635350, COSV100529232; called by muse, mutect2
- ARHGEF28 | c.2276T>C p.V759A | Missense Mutation (SNP) | VAF 6/103 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.093); catalogued as COSV99708870; called by muse, mutect2
- ARHGEF28 | c.4004G>A p.G1335D | Missense Mutation (SNP) | VAF 53/164 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as COSV55266045; called by muse, mutect2, varscan2
- ARMC3 | c.2064dup p.E689Rfs*20 | Frame Shift Ins (INS) | VAF 10/59 reads (17%) | catalogued as rs1564406625; called by mutect2, varscan2
- ARV1 | c.518del p.K173Sfs*8 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | catalogued as rs544784472, COSV59618356; called by mutect2, varscan2
- ASAP3 | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1448620878; called by muse, mutect2, varscan2
- ASH1L | c.8698del p.T2900Qfs*44 (on ENST00000368346 / NM_001366177.2; = p.T2895Qfs*44 on NM_018489.3) | Frame Shift Del (DEL) | VAF 32/130 reads (25%) | catalogued as rs761154268; called by mutect2, varscan2
- ATG2A | c.1694G>A p.R565H | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1242809115; called by muse, mutect2, varscan2
- ATG2B | c.3120del p.K1040Nfs*2 | Frame Shift Del (DEL) | VAF 12/88 reads (14%) | catalogued as rs771531141; called by mutect2, varscan2
- ATG9B | c.2162del p.P721Qfs*62 | Frame Shift Del (DEL) | VAF 17/132 reads (13%) | catalogued as COSV52486004; called by mutect2, pindel, varscan2
- ATP13A3 | c.262G>A p.V88I | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs189104648; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1663G>A p.G555S | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100023094; called by muse, mutect2
- ATP8A1 | c.1028A>T p.N343I | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV52544802; called by muse, mutect2, varscan2
- ATP8B2 | c.189G>T p.A63= (on ENST00000672630; = p.A30= on NM_001005855.2) | Splice Region (SNP) | VAF 20/87 reads (23%) | catalogued as COSV59244535, COSV59248075; called by muse, mutect2, varscan2
- B3GAT1 | c.40G>A p.V14M | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); catalogued as rs376707624; called by muse, mutect2, varscan2
- BAG3 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV64842499; called by muse, mutect2, varscan2
- BCAM | c.427G>A p.V143M | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.293); catalogued as rs778465310, COSV99538650; called by muse, mutect2, varscan2
- BCAR1 | c.1276C>T p.R426C | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs779814700; called by muse, mutect2, varscan2
- BCHE | c.1027del p.T343Pfs*16 | Frame Shift Del (DEL) | VAF 49/202 reads (24%) | catalogued as CM025285, COSV52257903; called by pindel, varscan2
- BCL2L2 | c.570del p.F190Lfs*55 | Frame Shift Del (DEL) | VAF 38/190 reads (20%) | catalogued as rs763348226; called by mutect2, pindel, varscan2
- BCL9L | c.3331G>A p.A1111T | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52685927; called by muse, mutect2, varscan2
- BEND3 | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.749); catalogued as rs782720317; called by muse, mutect2, varscan2
- BEND5 | c.1052del p.K351Rfs*15 | Frame Shift Del (DEL) | VAF 18/103 reads (17%) | catalogued as rs756345162, COSV65718189; called by mutect2, varscan2
- BICRA | c.2810del p.P937Hfs*10 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as rs755506199; called by mutect2, varscan2
- BMP10 | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.058); catalogued as rs537354595; called by muse, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 21/90 reads (23%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BOD1L1 | c.8602C>T p.P2868S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1303638793; called by muse, mutect2
- BRD4 | c.1462A>G p.S488G | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.607); catalogued as rs964801906; called by muse, mutect2, varscan2
- BRINP3 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66514914, COSV66524518; called by muse, mutect2, varscan2
- C1R | c.1728G>T p.E576D (on ENST00000536053 / NM_001354346.2; = p.E562D on NM_001733.7) | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV101605615; called by muse, mutect2
- C6orf201 | c.302del p.N101Mfs*8 | Frame Shift Del (DEL) | VAF 33/116 reads (28%) | catalogued as rs1438775096; called by mutect2, pindel, varscan2
- CACNA1H | c.6570del p.C2191Afs*26 | Frame Shift Del (DEL) | VAF 15/72 reads (21%) | catalogued as rs760298114; called by mutect2, pindel, varscan2
- CACNA2D3 | c.1936G>A p.D646N | Missense Mutation (SNP) | VAF 26/297 reads (9%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.997); catalogued as COSV55546323; called by muse, mutect2
- CACNG2 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.383); catalogued as rs1021475125; called by muse, mutect2, varscan2
- CAMSAP1 | c.1396del p.T466Pfs*46 | Frame Shift Del (DEL) | VAF 10/51 reads (20%) | catalogued as rs201838505; called by mutect2, varscan2
- CAPS2 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as rs542643144, COSV60828898; called by muse, mutect2
- CASD1 | c.1626del p.A543Qfs*13 | Frame Shift Del (DEL) | VAF 10/57 reads (18%) | catalogued as rs770159446; called by mutect2, varscan2
- CASZ1 | c.1268A>T p.N423I | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.332); catalogued as COSV100681210, COSV59734916; called by muse, mutect2, varscan2
- CCBE1 | c.95C>T p.T32M | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs944000197; called by muse, mutect2
- CCDC114 | c.1678G>A p.V560I | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.772); catalogued as rs1296287942, COSV59558134; called by muse, mutect2, varscan2
- CCDC180 | c.478G>A p.V160M | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as rs764896343, COSV63828808; called by muse, mutect2, varscan2
- CCDC28A | c.80del p.N27Mfs*5 | Frame Shift Del (DEL) | VAF 35/94 reads (37%) | catalogued as rs756347761; called by mutect2, varscan2
- CCDC73 | c.1913del p.N638Ifs*18 | Frame Shift Del (DEL) | VAF 20/61 reads (33%) | catalogued as rs762553129; called by mutect2, varscan2
- CCM2 | c.1012C>A p.L338M | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99348236; called by muse, mutect2, varscan2
- CD163L1 | c.2081G>A p.G694D | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.54); PolyPhen probably damaging (1); catalogued as COSV58015686; called by muse, mutect2, varscan2
- CDC42BPA | c.4557C>A p.D1519E (on ENST00000334218 / NM_001366019.2; = p.D1506E on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.306); catalogued as rs555844878, COSV62014441, COSV62017801; called by muse, mutect2, varscan2
- CDH10 | c.2168T>C p.L723P | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.218); catalogued as rs763423183, COSV100053397, COSV52579394, COSV52582499; called by muse, mutect2, varscan2
- CDH12 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 49/165 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1171594653, COSV101200838, COSV66444733; called by muse, mutect2, varscan2
- CEMIP | c.1324G>A p.A442T | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99586606; called by muse, mutect2
- CENPI | c.698C>A p.P233H | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as COSV99515903; called by muse, mutect2, varscan2
- CGN | c.1579G>C p.E527Q | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.874); catalogued as COSV54967871; called by muse, mutect2, varscan2
- CHD3 | c.5842G>A p.A1948T (on ENST00000330494 / NM_001005273.3; = p.A1914T on NM_005852.4) | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs1309516500, COSV57872130; called by muse, mutect2, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 38/136 reads (28%) | catalogued as rs751548647; called by mutect2, varscan2
- CHRNG | c.1487A>G p.H496R | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as COSV99299054; called by muse, varscan2
- CHST15 | c.761C>A p.P254Q | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs907644359, COSV100655114; called by muse, mutect2, varscan2
- CIBAR2 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1439309004, COSV73320649, COSV73320691; called by muse, mutect2, varscan2
- CIITA | c.2650C>T p.R884C | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs867810192, COSV60860761; called by muse, mutect2, varscan2
- CKB | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100818922; called by muse, mutect2, varscan2
- CLDN5 | c.59del p.G20Vfs*2 (on ENST00000618236 / NM_001363066.2; = p.G105Vfs*2 on NM_003277.4) | Frame Shift Del (DEL) | VAF 34/153 reads (22%) | catalogued as rs768198935; called by mutect2, pindel, varscan2
- CLPTM1 | c.1765C>T p.R589C | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1451869340, COSV61612689; called by muse, mutect2, varscan2
- CLSTN3 | c.2858del p.P953Hfs*106 | Frame Shift Del (DEL) | VAF 13/70 reads (19%) | catalogued as rs758841384; called by mutect2, pindel, varscan2
- CLUH | c.2480C>T p.T827M (on ENST00000435359; = p.T866M on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/282 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as rs769848334, COSV70929020; called by muse, mutect2, varscan2
- CMYA5 | c.1669C>T p.H557Y | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV71408637; called by muse, mutect2, varscan2
- CMYA5 | c.4504G>T p.V1502F | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.31); catalogued as COSV71408640; called by muse, mutect2, varscan2
- CNGB1 | c.3505G>A p.A1169T | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs780554214; called by muse, mutect2, varscan2
- CNOT6 | c.750del p.L251Wfs*2 | Frame Shift Del (DEL) | VAF 10/118 reads (8%) | catalogued as COSV56160927; called by mutect2, pindel
- CNTN6 | c.55G>T p.G19C | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV100610690; called by muse, mutect2, varscan2
- CNTNAP4 | c.776T>C p.V259A | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.64); PolyPhen benign (0.142); catalogued as COSV56695049; called by muse, mutect2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | catalogued as rs374805044; called by mutect2, varscan2
- COG1 | c.2073+1G>A p.X691_splice | Splice Site (SNP) | VAF 9/54 reads (17%) | catalogued as COSV100245268; called by muse, mutect2, varscan2
- COL25A1 | c.1657-3del | Splice Region (DEL) | VAF 14/109 reads (13%) | catalogued as rs760493024; called by mutect2, varscan2
- COX10 | c.630dup p.E211* | Frame Shift Ins (INS) | VAF 6/36 reads (17%) | catalogued as rs1364224981; called by pindel, varscan2
- CPNE8 | c.934G>A p.V312M | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1289612211, COSV58838654; called by muse, mutect2
- CRAMP1 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 15/190 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs771115810, COSV51960460, COSV99245864; called by muse, mutect2
- CSF1 | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.761); catalogued as rs765157738; called by muse, mutect2, varscan2
- CSF3R | c.1404del p.S469Afs*22 | Frame Shift Del (DEL) | VAF 9/49 reads (18%) | catalogued as rs747437399; called by mutect2, pindel, varscan2
- CSNK1G3 | c.145del p.I49Lfs*11 | Frame Shift Del (DEL) | VAF 25/121 reads (21%) | catalogued as rs775129818, COSV62054115, COSV62057434; called by mutect2, varscan2
- CTLA4 | c.529del p.Y177Ifs*10 | Frame Shift Del (DEL) | VAF 12/90 reads (13%) | catalogued as COSV55593336; called by mutect2, pindel, varscan2
- CTNND1 | c.2225G>A p.R742H (on ENST00000399050 / NM_001085458.2; = p.R736H on NM_001331.3) | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs201606412, COSV62382159; called by muse, mutect2
- CXCR4 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54010912, COSV54015485; called by muse, mutect2, varscan2
- CYP2D6 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 19/281 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.097); catalogued as rs75386357, CM092491; called by muse, mutect2
- CYP7B1 | c.1457G>A p.R486H | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs755729966, COSV59599273; called by muse, mutect2, varscan2
- DCAF4L2 | c.994G>A p.V332M | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747432904, COSV60479126, COSV60479633; called by muse, mutect2
- DCLK2 | c.2150C>A p.P717H | Missense Mutation (SNP) | VAF 33/268 reads (12%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV56202293; called by muse, mutect2, varscan2
- DGKG | c.1675C>T p.H559Y | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV99403116; called by muse, mutect2
- DHRS1 | c.725-5C>T | Splice Region (SNP) | VAF 32/78 reads (41%) | catalogued as rs370794166; called by muse, mutect2, varscan2
- DHX36 | c.1270C>T p.Q424* | Nonsense Mutation (SNP) | VAF 16/90 reads (18%) | catalogued as COSV57674794; called by muse, mutect2, varscan2
- DLAT | c.342del p.E115Rfs*10 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | catalogued as rs782180715; called by mutect2, varscan2
- DLGAP2 | c.2203-2A>C p.X735_splice | Splice Site (SNP) | VAF 27/93 reads (29%) | catalogued as COSV101421714; called by muse, mutect2, varscan2
- DMAP1 | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 19/214 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1243798144, COSV60001472; called by muse, mutect2
- DMBT1 | c.5636-1G>T p.X1879_splice (on ENST00000338354 / NM_001377530.1; = p.X1122_splice on NM_004406.3) | Splice Site (SNP) | VAF 15/61 reads (25%) | catalogued as COSV57555344; called by muse, mutect2, varscan2
- DMD | c.4940C>T p.T1647M | Missense Mutation (SNP) | VAF 44/81 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs148868095, COSV63780503; ClinVar: benign; called by muse, mutect2, varscan2
- DMP1 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.705); catalogued as COSV56821741; called by muse, mutect2, varscan2
- DNA2 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.536); catalogued as COSV64429702; called by muse, mutect2
- DNAH8 | c.7821del p.F2607Lfs*22 | Frame Shift Del (DEL) | VAF 23/72 reads (32%) | catalogued as rs759301439, COSV100547129; called by mutect2, pindel, varscan2
- DNAI3 | c.2084A>G p.N695S | Missense Mutation (SNP) | VAF 36/201 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs754663752; called by muse, mutect2, varscan2
- DNAL4 | c.211G>A p.V71M | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs369007384; called by muse, mutect2, varscan2
- DNMT3B | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); catalogued as rs770859652, COSV52415517; called by muse, mutect2, varscan2
- DOCK3 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs1325377187, COSV56530671; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK5 | c.2662G>A p.G888S | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.156); catalogued as rs772557421, COSV52404020; called by muse, mutect2, varscan2
- DOK1 | c.1211C>T p.P404L | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.362); catalogued as rs753672963, COSV51211537; called by muse, mutect2, varscan2
- DUOXA1 | c.92T>G p.F31C | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as COSV99973108; called by muse, mutect2
- DVL2 | c.1811C>T p.T604M | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.439); catalogued as rs773310143, COSV50035584; called by muse, mutect2
- DYRK1B | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1291364341; called by muse, mutect2, varscan2
- DYSF | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as rs1449509021; called by muse, mutect2, varscan2
- DYSF | c.544del p.A182Lfs*45 | Frame Shift Del (DEL) | VAF 14/86 reads (16%) | catalogued as COSV99246632; called by mutect2, varscan2
- DYSF | c.2617G>T p.G873W | Missense Mutation (SNP) | VAF 30/303 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50470793, COSV99249582; called by muse, mutect2, varscan2
- EDNRB | c.1147del p.Y383Ifs*3 (on ENST00000377211 / NM_001201397.1; = p.Y293Ifs*3 on NM_000115.5) | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | catalogued as rs769735757; ClinVar: risk factor; called by pindel, varscan2
- EEA1 | c.856T>C p.Y286H | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV59285983; called by muse, mutect2, varscan2
- EEF2KMT | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 51/309 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV69863703; called by muse, mutect2, varscan2
- EFCAB13 | c.1024del p.S342Afs*25 | Frame Shift Del (DEL) | VAF 13/75 reads (17%) | catalogued as rs759569556; called by mutect2, pindel, varscan2
- EIF5B | c.1906G>A p.V636I | Missense Mutation (SNP) | VAF 25/204 reads (12%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.985); catalogued as rs1344674132; called by muse, mutect2, varscan2
- EML6 | c.937C>T p.R313* | Nonsense Mutation (SNP) | VAF 32/113 reads (28%) | catalogued as rs1379514961; called by muse, mutect2, varscan2
- ENPP2 | c.2482C>T p.R828C (on ENST00000075322 / NM_001040092.3; = p.R880C on NM_006209.5) | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752514086; called by muse, mutect2
- EP400 | c.1952C>A p.P651H | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.639); catalogued as COSV57786885; called by muse, mutect2, varscan2
- EPS8L1 | c.2045G>A p.R682H (on ENST00000201647 / NM_133180.3; = p.R555H on NM_017729.3) | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV52385104; called by muse, mutect2, varscan2
- EPS8L2 | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 17/234 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as rs1554952298, COSV59349778; called by muse, mutect2
- ERICH6 | c.1810C>T p.R604C | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs373884223; called by muse, mutect2, varscan2
- ERMP1 | c.1951del p.T651Pfs*3 | Frame Shift Del (DEL) | VAF 28/128 reads (22%) | catalogued as rs753821453; called by mutect2, varscan2
- ESPL1 | c.1669G>A p.A557T | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.046); catalogued as rs1315725035; called by muse, mutect2, varscan2
- EVC2 | c.3386C>T p.A1129V | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as rs758710828; called by muse, mutect2, varscan2
- EVPL | c.2450C>T p.A817V | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as rs1309525993; called by muse, mutect2, varscan2
- FAHD2B | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 58/166 reads (35%) | catalogued as rs751966944; called by mutect2, varscan2
- FAM114A1 | c.1651G>A p.V551I | Missense Mutation (SNP) | VAF 13/221 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100729272; called by muse, mutect2
- FAM155A | c.595dup p.A199Gfs*29 | Frame Shift Ins (INS) | VAF 7/30 reads (23%) | catalogued as rs775872623; called by mutect2, pindel, varscan2
- FAM161B | c.882A>C p.Q294H (on ENST00000651776; = p.Q231H on NM_152445.3) | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.132); catalogued as COSV54103683; called by muse, varscan2
- FAM83E | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748353296; called by muse, mutect2, varscan2
- FAM98C | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.562); catalogued as rs200101425; called by muse, mutect2, varscan2
- FAM9A | c.477del p.K159Nfs*3 | Frame Shift Del (DEL) | VAF 10/66 reads (15%) | catalogued as rs748967872; called by mutect2, varscan2
- FANCG | c.1546G>A p.A516T | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as rs199833626; called by muse, mutect2, varscan2
- FAT3 | c.5649T>G p.F1883L | Missense Mutation (SNP) | VAF 63/196 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.137); catalogued as COSV53157376; called by muse, mutect2, varscan2
- FBXO21 | c.1808G>A p.R603Q (on ENST00000330622 / NM_033624.3; = p.R596Q on NM_015002.3) | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as rs769009614, COSV100401581; called by muse, mutect2, varscan2
- FCER2 | c.850C>T p.R284W | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs780858530; called by mutect2, varscan2
- FCGRT | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs777748221; called by muse, mutect2
- FCRL3 | c.814dup p.R272Kfs*16 | Frame Shift Ins (INS) | VAF 16/60 reads (27%) | catalogued as rs1288807478; called by mutect2, varscan2
- FERMT1 | c.1885G>A p.V629I | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0.02); catalogued as rs1347340686; called by muse, mutect2, varscan2
- FIZ1 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.967); catalogued as rs1411972472; called by muse, mutect2, varscan2
- FLG | c.3100G>A p.G1034R | Missense Mutation (SNP) | VAF 64/180 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs780634554, COSV64243291, COSV64246746; called by muse, mutect2, varscan2
- FOLR3 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 52/252 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs752321934; called by muse, mutect2, varscan2
- FRY | c.311C>A p.P104H | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.76); catalogued as COSV100969130, COSV66580972; called by muse, mutect2
- FYN | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs746134687, COSV57617871; called by muse, mutect2, varscan2
- FZD3 | c.413C>A p.P138H | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV99528052; called by muse, mutect2
- GABBR2 | c.1662+1G>A p.X554_splice | Splice Site (SNP) | VAF 30/112 reads (27%) | catalogued as COSV99409801; called by muse, mutect2, varscan2
- GABRB2 | c.1159C>T p.R387W | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs140795978; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GABRG3 | c.1183G>A p.V395I | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as rs375624145; called by muse, mutect2, varscan2
- GABRQ | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782548142, COSV64781159; called by muse, mutect2, varscan2
- GALK2 | c.632G>T p.R211M | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV59100266; called by muse, mutect2, varscan2
- GBP3 | c.1753del p.T585Pfs*9 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | catalogued as rs548474277; called by mutect2, varscan2
- GDI1 | c.1006A>G p.M336V | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as rs782169795, COSV50130697; called by muse, mutect2, varscan2
- GFM2 | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 21/357 reads (6%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.832); catalogued as rs371589931; called by muse, mutect2
- GFOD1 | c.1120G>A p.A374T | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.123); catalogued as rs1242143802, COSV64954773; called by mutect2, varscan2
- GHSR | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 8/155 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as COSV99576892; called by muse, mutect2
- GIMAP7 | c.135G>T p.K45N | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV57960301; called by muse, mutect2, varscan2
- GLI3 | c.3392C>T p.A1131V | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs750890276, COSV67889541; called by muse, mutect2, varscan2
- GNAL | c.1018G>A p.G340S (on ENST00000269162 / NM_001142339.3; = p.G417S on NM_182978.4) | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs142792291; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GNL3L | c.532G>A p.V178I | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.348); catalogued as COSV100328306; called by muse, mutect2, varscan2
- GPATCH8 | c.4505C>T p.T1502M | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as rs761075475, COSV100132609; called by muse, mutect2, varscan2
- GPR108 | c.1351-1G>T p.X451_splice (on ENST00000264080 / NM_001080452.1; = p.X209_splice on NM_020171.2) | Splice Site (SNP) | VAF 20/74 reads (27%) | catalogued as COSV51186544; called by muse, mutect2
- GPR12 | c.627G>A p.M209I | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV101197970; called by muse, mutect2
- GPR6 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV51571736; called by muse, mutect2
- GREB1L | c.3751C>T p.P1251S | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99337347; called by muse, mutect2, varscan2
- GRIN2C | c.1807G>A p.V603M | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs1378331673, COSV99500900; called by muse, mutect2
- GRIPAP1 | c.2277C>T p.I759= | Splice Region (SNP) | VAF 43/115 reads (37%) | catalogued as rs144855492, COSV54413534, COSV54415427; called by muse, mutect2, varscan2
- GRSF1 | c.664G>A p.V222M | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs923344198; called by muse, mutect2, varscan2
- GTF2F1 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as rs1209004307, COSV101081443; called by muse, mutect2, varscan2
- GTF3C1 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.952); catalogued as COSV62240723; called by muse, mutect2
- GTF3C3 | c.422C>A p.P141H | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV99826644; called by muse, mutect2
- GTPBP6 | c.1303C>T p.P435S | Missense Mutation (SNP) | VAF 62/120 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.281); catalogued as rs757364188; called by muse, mutect2, varscan2
- GUCY1A2 | c.2135C>T p.S712L | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.574); catalogued as rs1383258563, COSV56477773; called by muse, mutect2, varscan2
- H3-2 | c.268G>A p.V90M | Missense Mutation (SNP) | VAF 40/249 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.96); catalogued as rs587771651; called by mutect2, varscan2
- HAL | c.855C>T p.Y285= | Splice Region (SNP) | VAF 24/116 reads (21%) | catalogued as rs201094537, COSV99701379; called by muse, mutect2, varscan2
- HASPIN | c.1782del p.F594Lfs*19 | Frame Shift Del (DEL) | VAF 16/101 reads (16%) | catalogued as rs1199479648; called by mutect2, pindel, varscan2
- HDAC8 | c.658G>T p.G220W | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101003269; called by muse, mutect2, varscan2
- HECTD4 | c.11878A>G p.T3960A | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV66397395; called by muse, mutect2
- HECW1 | c.4352G>A p.G1451D | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV67836972; called by muse, mutect2
- HERC5 | c.418del p.I140* | Frame Shift Del (DEL) | VAF 16/76 reads (21%) | catalogued as rs770854785; called by mutect2, varscan2
- HERC5 | c.1879G>A p.V627I | Missense Mutation (SNP) | VAF 62/212 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.266); catalogued as rs148569726; called by muse, mutect2, varscan2
- HHLA2 | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs768241814; called by mutect2, varscan2
- HLA-B | c.782G>C p.G261A | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV69520264, COSV69523228; called by muse, mutect2, varscan2
- HMGCS2 | c.829del p.I277Sfs*22 | Frame Shift Del (DEL) | VAF 23/104 reads (22%) | catalogued as rs1557991740, COSV65568693; called by mutect2, pindel, varscan2
- HNRNPM | c.371G>T p.S124I | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.965); catalogued as COSV100335307; called by muse, mutect2, varscan2
- HOMEZ | c.1127del p.L376Yfs*14 | Frame Shift Del (DEL) | VAF 38/224 reads (17%) | catalogued as rs755016625; called by mutect2, varscan2
- HRH3 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as rs751534866, COSV58050294; called by muse, mutect2, varscan2
- HSP90AA1 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV53489469; called by muse, mutect2, varscan2
- HSPA1B | c.71G>A p.G24D | Missense Mutation (SNP) | VAF 76/303 reads (25%) | SIFT tolerated, low confidence (0.4); PolyPhen probably damaging (0.957); catalogued as COSV65148506; called by muse, mutect2, varscan2
- HSPB3 | c.432G>T p.K144N | Missense Mutation (SNP) | VAF 12/177 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV100115915; called by muse, mutect2
- HSPG2 | c.12907C>T p.R4303C | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs761987723; called by muse, mutect2, varscan2
- IFIT2 | c.815del p.K272Rfs*3 | Frame Shift Del (DEL) | VAF 11/101 reads (11%) | catalogued as COSV51078943; called by mutect2, pindel, varscan2
- IFRD2 | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs782709559, COSV57112695; called by muse, mutect2, varscan2
- IGFALS | c.1267G>A p.V423M | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as rs200564045, COSV51905097, COSV99236303; called by muse, mutect2, varscan2
- IKBKE | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs782704785, COSV65625982; called by muse, varscan2
- IL10RB | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1058861, COSV51615105; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IL1RL2 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 63/185 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.148); catalogued as rs748205889, COSV51814833; called by muse, mutect2, varscan2
- IL27RA | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs374355041; called by muse, mutect2, varscan2
- INO80E | c.531del p.D178Tfs*8 | Frame Shift Del (DEL) | VAF 40/156 reads (26%) | catalogued as rs1339809802; called by pindel, varscan2
- INPPL1 | c.2719C>T p.R907* | Nonsense Mutation (SNP) | VAF 33/104 reads (32%) | catalogued as rs781674896, CM130298; called by muse, mutect2, varscan2
- IRS1 | c.1791del p.H598Tfs*38 | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | catalogued as rs761880048; called by mutect2, varscan2
- ISLR | c.263C>T p.T88M | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); catalogued as rs199636609, COSV99997444; called by muse, mutect2, varscan2
- ITGA8 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.191); catalogued as rs755500317, COSV65232771; called by muse, mutect2, varscan2
- ITIH5 | c.2690A>G p.N897S | Missense Mutation (SNP) | VAF 7/165 reads (4%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.911); catalogued as rs948760624; called by muse, mutect2
- JADE1 | c.1478C>T p.T493M | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.931); catalogued as rs371885369; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs112995620; called by muse, mutect2, varscan2
- JRK | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs781950867, COSV101401087; called by muse, mutect2, varscan2
- KCNH1 | c.1897G>A p.E633K (on ENST00000271751 / NM_172362.3; = p.E606K on NM_002238.4) | Missense Mutation (SNP) | VAF 79/246 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55072752; called by muse, mutect2, varscan2
- KCNJ3 | c.419C>T p.T140M | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99715661; called by muse, mutect2, varscan2
- KCNMA1 | c.2306del p.K769Sfs*17 (on ENST00000286628 / NM_001161352.2; = p.K711Sfs*17 on NM_002247.4) | Frame Shift Del (DEL) | VAF 50/112 reads (45%) | catalogued as rs771351714; called by mutect2, varscan2
- KCNQ4 | c.1960G>A p.A654T | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as COSV100714464; called by muse, mutect2
- KDM2B | c.376C>T p.R126* | Nonsense Mutation (SNP) | VAF 20/125 reads (16%) | catalogued as rs1555316567, COSV65639848; called by muse, mutect2, varscan2
- KDM5A | c.3597del p.G1200Dfs*9 | Frame Shift Del (DEL) | VAF 17/106 reads (16%) | catalogued as rs771545848; called by mutect2, varscan2
- KDM5C | c.2866G>A p.A956T | Missense Mutation (SNP) | VAF 48/78 reads (62%) | SIFT tolerated (0.48); PolyPhen benign (0.014); catalogued as rs1392496114; called by muse, mutect2, varscan2
- KHNYN | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1269060480; called by muse, mutect2, varscan2
- KIF12 | c.328C>T p.Q110* | Nonsense Mutation (SNP) | VAF 45/125 reads (36%) | catalogued as COSV100936105; called by muse, mutect2, varscan2
- KIF1A | c.1817G>A p.R606H | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs764578297; called by muse, mutect2, varscan2
- KIF26A | c.3440del p.P1147Lfs*101 | Frame Shift Del (DEL) | VAF 14/142 reads (10%) | catalogued as rs771825279; called by mutect2, pindel
- KLRG2 | c.1095del p.L366Sfs*67 | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | catalogued as COSV61801424; called by mutect2, varscan2
- KRT33B | c.19C>A p.L7M | Missense Mutation (SNP) | VAF 11/211 reads (5%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.998); catalogued as COSV99290585; called by muse, mutect2
- KRT84 | c.1579C>A p.L527M | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.215); catalogued as COSV99230835; called by muse, mutect2
- KRTAP12-1 | c.272G>A p.S91N | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV59974529; called by muse, mutect2
- KRTAP20-4 | c.7T>C p.Y3H | Missense Mutation (SNP) | VAF 10/137 reads (7%) | catalogued as COSV100587968; called by muse, mutect2
- LAMC1 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV51132524, COSV99278997; called by muse, mutect2, varscan2
- LDLRAP1 | c.167C>T p.T56M | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs752849346, CM100920, COSV65473218; called by muse, mutect2, varscan2
- LDOC1 | c.241C>T p.R81* | Nonsense Mutation (SNP) | VAF 43/74 reads (58%) | catalogued as COSV65159579; called by muse, mutect2, varscan2
- LEF1 | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99489512; called by muse, mutect2
- LHX9 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.608); catalogued as rs920489029; called by muse, mutect2, varscan2
- LOXL3 | c.1472G>A p.R491H | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as rs772977368; called by muse, mutect2, varscan2
- LPAR5 | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as rs1009034715, COSV61693303; called by muse, mutect2
- LRP1 | c.2515G>T p.G839C | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs571557412; called by muse, mutect2, varscan2
- LRRC14B | c.163G>T p.G55W | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as COSV99360172; called by muse, mutect2, varscan2
- LRRK2 | c.2717del p.K906Rfs*8 | Frame Shift Del (DEL) | VAF 17/66 reads (26%) | catalogued as COSV54156711; called by mutect2, pindel, varscan2
- LSR | c.1812_1814del p.R605del (on ENST00000361790; = p.R586del on NM_015925.6) | In Frame Del (DEL) | VAF 6/44 reads (14%) | catalogued as rs1370643301; called by pindel, varscan2
- LUZP2 | c.469dup p.I157Nfs*18 | Frame Shift Ins (INS) | VAF 31/121 reads (26%) | catalogued as rs766421606; called by mutect2, varscan2
- LYN | c.327del p.E110Kfs*15 | Frame Shift Del (DEL) | VAF 10/67 reads (15%) | catalogued as rs1266824391, COSV99066642; called by mutect2, pindel, varscan2
- LYPLA1 | c.554C>T p.T185M | Missense Mutation (SNP) | VAF 27/362 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as rs767257936, COSV57604708; called by muse, mutect2
- MACROD2 | c.271G>T p.A91S | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as rs1256648187, COSV53975817, COSV54059394; called by muse, mutect2
- MAGEA4 | c.791G>A p.G264D | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.133); catalogued as rs1274181760, COSV52342657; called by muse, mutect2, varscan2
- MBNL1 | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); catalogued as COSV56833651; called by muse, mutect2
- MCM3AP | c.3536G>A p.R1179H | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.057); catalogued as rs750063536, COSV52441719; called by muse, mutect2, varscan2
- MCTP1 | c.1904C>T p.A635V | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); catalogued as COSV56503691; called by muse, mutect2, varscan2
- MEGF8 | c.6428del p.G2143Afs*20 (on ENST00000251268 / NM_001271938.2; = p.G2076Afs*20 on NM_001410.3) | Frame Shift Del (DEL) | VAF 9/41 reads (22%) | catalogued as rs1258909672; called by mutect2, pindel, varscan2
- MINDY4 | c.1861G>T p.D621Y | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99518539; called by muse, mutect2, varscan2
- MMD2 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV68659756; called by muse, mutect2, varscan2
- MORC4 | c.1942G>T p.G648W | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV55245517; called by muse, mutect2, varscan2
- MORN1 | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.878); catalogued as rs866880131; called by muse, mutect2, varscan2
- MPG | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs866971335, COSV99549908; called by muse, mutect2
- MROH7 | c.2204A>G p.Y735C | Missense Mutation (SNP) | VAF 53/219 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs1163821234; called by mutect2, varscan2
- MRPL38 | c.563A>G p.Y188C | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs539600238; called by muse, mutect2, varscan2
- MRPL54 | c.52del p.A18Pfs*5 | Frame Shift Del (DEL) | VAF 40/151 reads (26%) | catalogued as COSV57462495; called by mutect2, pindel, varscan2
- MSH3 | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.255); catalogued as rs138381683, COSV99432546; called by muse, mutect2, varscan2
- MST1 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs745819788, COSV56536015, COSV56537281; called by muse, mutect2, varscan2
- MTA1 | c.905A>G p.K302R | Missense Mutation (SNP) | VAF 61/213 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as COSV58759557; called by muse, mutect2, varscan2
- MTA1 | c.1123G>A p.G375S | Missense Mutation (SNP) | VAF 30/362 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs139214108, COSV58760240; called by muse, mutect2
- MTSS1 | c.459del p.R155Efs*34 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | catalogued as rs1563799887; called by mutect2, pindel, varscan2
- MTUS1 | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs373564089; called by muse, mutect2, varscan2
- MUC16 | c.39156G>T p.K13052N | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.595); catalogued as COSV67484253; called by muse, mutect2, varscan2
- MUC16 | c.19333A>G p.I6445V | Missense Mutation (SNP) | VAF 16/255 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as COSV101199554; called by muse, mutect2
- MUC4 | c.4586C>T p.A1529V | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated, low confidence (0.54); PolyPhen possibly damaging (0.494); catalogued as rs201310867; called by mutect2, varscan2
- MYH1 | c.3353G>T p.R1118L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs377745179, COSV104388939, COSV56846660; called by muse, mutect2, varscan2
- MYO18B | c.5008C>T p.R1670W | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as rs768378762; called by muse, mutect2, varscan2
- MYO5A | c.1841G>A p.R614Q | Missense Mutation (SNP) | VAF 50/171 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.322); catalogued as rs751663129, COSV100697518; called by muse, mutect2, varscan2
- NAA80 | c.494G>A p.R165Q (on ENST00000417393 / NM_001200018.2; = p.R187Q on NM_012191.4) | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as rs763891675; called by muse, mutect2, varscan2
- NAT10 | c.745G>T p.G249C | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.397); catalogued as COSV99140072; called by muse, mutect2
- NBEA | c.5912G>A p.C1971Y | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV100079880; called by muse, mutect2
- NCOR2 | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1012459312, COSV62293396; called by muse, mutect2
- NEB | c.16481C>T p.T5494I | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200104698, COSV50806862; called by muse, mutect2, varscan2
- NEO1 | c.3742+1G>A p.X1248_splice | Splice Site (SNP) | VAF 32/127 reads (25%) | catalogued as rs747725504, COSV99981617; called by muse, mutect2, varscan2
- NEPRO | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100075003; called by muse, mutect2
- NF1 | c.2659G>A p.A887T | Missense Mutation (SNP) | VAF 11/167 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.037); catalogued as rs1251621684, COSV62203236; ClinVar: uncertain significance; called by muse, mutect2
- NFATC1 | c.420G>T p.E140D | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV53706841; called by muse, mutect2, varscan2
- NIPA1 | c.706G>A p.V236M | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs766212364, COSV61680498; called by muse, mutect2, varscan2
- NIPA2 | c.98del p.K33Rfs*12 | Frame Shift Del (DEL) | VAF 17/49 reads (35%) | catalogued as rs145147241; called by mutect2, varscan2
- NKPD1 | c.1453G>A p.A485T | Missense Mutation (SNP) | VAF 14/211 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100521561; called by muse, mutect2
- NKPD1 | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1383235352; called by muse, mutect2, varscan2
- NLRP3 | c.941G>A p.G314E | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV60231764, COSV60232893; called by muse, mutect2, varscan2
- NMUR2 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 54/186 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs779708928, COSV54917163; called by muse, mutect2, varscan2
- NOC4L | c.149T>C p.V50A | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1230717544, COSV57959571; called by muse, mutect2, varscan2
- NOL6 | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 42/197 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs115808915; called by muse, mutect2, varscan2
- NOS2 | c.1054G>A p.V352M | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100569617; called by muse, mutect2
- NPAS2 | c.197C>T p.T66M | Missense Mutation (SNP) | VAF 45/179 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.372); catalogued as rs775528411; called by muse, mutect2, varscan2
- NPHP4 | c.3169G>A p.E1057K | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755465110; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPPA | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1803268, COSV56742385; called by muse, mutect2, varscan2
- NUP85 | c.386G>A p.G129D | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.075); catalogued as COSV55466962; called by muse, mutect2, varscan2
- NUP98 | c.3034C>T p.R1012C (on ENST00000359171 / NM_001365126.1; = p.R995C on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.316); catalogued as rs144100440, COSV61436913; called by muse, mutect2, varscan2
- NXPE3 | c.1456G>A p.A486T | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.022); catalogued as rs1446190351, COSV56292922; called by muse, mutect2, varscan2
- NXPE4 | c.611T>C p.F204S | Missense Mutation (SNP) | VAF 9/228 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as COSV100970399; called by muse, mutect2
- NXPH3 | c.272del p.P91Hfs*6 | Frame Shift Del (DEL) | VAF 11/74 reads (15%) | catalogued as rs915044706; called by mutect2, pindel, varscan2
- ODAPH | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as rs756454916, COSV61140864, COSV61141580; called by muse, mutect2, varscan2
- OR2T33 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 77/357 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as rs758676398, COSV100531755; called by muse, mutect2, varscan2
- OR4C46 | c.271C>A p.L91I | Missense Mutation (SNP) | VAF 12/187 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.045); catalogued as rs1455331515; called by muse, mutect2
- OR7G1 | c.616T>C p.F206L | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.98); PolyPhen benign (0.02); catalogued as rs769241314; called by muse, mutect2, varscan2
- OVGP1 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.839); catalogued as rs763371520; called by muse, mutect2, varscan2
- PABPC1 | c.1748G>A p.G583D | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59400112; called by muse, mutect2, varscan2
- PABPN1L | c.185A>G p.D62G | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99967594; called by muse, mutect2, varscan2
- PAFAH1B1 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 15/408 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); catalogued as rs868052564, COSV68210430; called by muse, mutect2
- PAPLN | c.3595T>C p.S1199P (on ENST00000554301; = p.S1172P on NM_173462.4) | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53721964; called by muse, mutect2, varscan2
- PAPPA2 | c.1739G>A p.R580Q | Missense Mutation (SNP) | VAF 60/186 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); catalogued as rs777147973, COSV62783931; called by muse, mutect2, varscan2
- PARP1 | c.313A>G p.K105E | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.74); PolyPhen benign (0.052); catalogued as rs1289654275; called by muse, mutect2, varscan2
- PARS2 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs879231179, COSV64883672; called by muse, mutect2
- PAXIP1 | c.3133+5G>A | Splice Region (SNP) | VAF 31/140 reads (22%) | catalogued as COSV66898825; called by muse, mutect2, varscan2
- PAXIP1 | c.2020G>A p.A674T | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68184797; called by muse, mutect2, varscan2
- PCDH17 | c.1432G>A p.V478M | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.066); catalogued as COSV100931479, COSV100931533; called by muse, mutect2, varscan2
- PCDHA4 | c.2024C>T p.A675V | Missense Mutation (SNP) | VAF 35/195 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.009); catalogued as rs1554125084, COSV63541767; called by muse, mutect2, varscan2
- PCDHA8 | c.896C>T p.T299M | Missense Mutation (SNP) | VAF 63/248 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.975); catalogued as rs145025203; called by muse, mutect2, varscan2
- PCF11 | c.1286del p.K429Rfs*7 | Frame Shift Del (DEL) | VAF 22/85 reads (26%) | catalogued as rs747292217; called by mutect2, pindel, varscan2
- PCLO | c.1330C>T p.P444S | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV61657328; called by muse, mutect2, varscan2
- PDE1A | c.1562A>G p.Q521R | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV100113967; called by muse, mutect2
- PDHX | c.1391G>A p.R464H | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs760454961, COSV57164035; called by muse, mutect2, varscan2
- PDK2 | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as rs1331470368, COSV50304510; called by muse, mutect2
- PEPD | c.541G>A p.V181I | Missense Mutation (SNP) | VAF 74/205 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs372629704, COSV54887070; called by muse, mutect2, varscan2
- PEX6 | c.1409G>C p.G470A | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1561823098, COSV99770111; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PFKP | c.1868C>T p.T623M | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.847); catalogued as rs1411129468, COSV66891411; called by muse, mutect2, varscan2
- PGLYRP1 | c.570G>A p.W190* | Nonsense Mutation (SNP) | VAF 10/162 reads (6%) | catalogued as rs1173103089; called by muse, mutect2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | catalogued as rs769717544; called by mutect2, varscan2
- PIK3R1 | c.1601G>A p.R534Q (on ENST00000521381 / NM_181523.3; = p.R264Q on NM_181504.4) | Missense Mutation (SNP) | VAF 88/320 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV57131725; called by muse, mutect2, varscan2
- PINK1 | c.1048G>A p.V350M | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764648391, COSV58630890; called by muse, mutect2, varscan2
- PIP4P2 | c.538del p.I180Sfs*21 | Frame Shift Del (DEL) | VAF 11/26 reads (42%) | catalogued as rs1158949501; called by mutect2, varscan2
- PIWIL2 | c.1841C>T p.A614V | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.048); catalogued as rs761129029; called by muse, mutect2, varscan2
- PKD2L1 | c.349+1G>A p.X117_splice | Splice Site (SNP) | VAF 10/48 reads (21%) | catalogued as rs556490027, COSV100559289; called by muse, mutect2, varscan2
- PLA2G4E | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as rs189961279, COSV68151261; called by muse, mutect2, varscan2
- PLCD1 | c.1723G>A p.V575M | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1007266827, COSV99378745; called by muse, mutect2
- PLCG2 | c.1177G>A p.A393T | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as rs760949449; called by muse, mutect2, varscan2
- PLPPR4 | c.1973G>A p.R658H | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.861); catalogued as rs754693317, COSV64564446; called by muse, mutect2
- PLXNA4 | c.4981G>T p.G1661* | Nonsense Mutation (SNP) | VAF 12/189 reads (6%) | catalogued as COSV58122581, COSV58152095, COSV58162874; called by muse, mutect2
- PLXNB3 | c.2026C>T p.R676C | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.386); catalogued as rs782515421, COSV62797735; called by muse, mutect2, varscan2
- PLXND1 | c.4352C>T p.A1451V | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368069685; called by muse, mutect2, varscan2
- PLXND1 | c.3097G>A p.A1033T | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs1026421973, COSV60712237; called by muse, mutect2
- PML | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs995136133, COSV51443198; called by muse, mutect2, varscan2
- PODN | c.908del p.P303Rfs*7 (on ENST00000395871; = p.P255Rfs*7 on NM_153703.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 8/55 reads (15%) | catalogued as rs1464111568, COSV57017199; called by mutect2, pindel, varscan2
- POTEF | c.2197T>C p.S733P | Missense Mutation (SNP) | VAF 26/544 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.077); catalogued as COSV62543315; called by muse, mutect2
- POU2F1 | c.817C>T p.R273* (on ENST00000541643 / NM_001365848.1; = p.R296* on NM_002697.4) | Nonsense Mutation (SNP) | VAF 30/161 reads (19%) | catalogued as rs1557950321, COSV54817774; called by muse, mutect2, varscan2
- PPM1M | c.341G>A p.G114D (on ENST00000296487; = p.G275D on NM_144641.4) | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.021); catalogued as rs764649883; called by muse, varscan2
- PPP1R3A | c.1407del p.K469Nfs*11 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | catalogued as COSV52885548; called by mutect2, pindel, varscan2
- PRDM6 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.097); catalogued as rs1488720108; called by muse, mutect2, varscan2
- PRDM6 | c.979C>T p.R327* | Nonsense Mutation (SNP) | VAF 16/100 reads (16%) | catalogued as COSV68335846; called by muse, mutect2, varscan2
- PRKCH | c.1075C>T p.R359* | Nonsense Mutation (SNP) | VAF 102/381 reads (27%) | catalogued as rs1401498476, COSV60647101; called by muse, varscan2
- PRLR | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.556); catalogued as COSV99184333; called by muse, mutect2
- PROKR1 | c.916G>A p.V306M | Missense Mutation (SNP) | VAF 57/203 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.557); catalogued as rs143892402, COSV58136477; called by muse, mutect2, varscan2
- PTGFRN | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV67799768; called by muse, mutect2, varscan2
- PTPRF | c.2468G>A p.R823Q | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.36); catalogued as rs565543436, COSV63443518; called by muse, mutect2, varscan2
- PTPRN | c.1306G>T p.A436S | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs780320168; called by muse, mutect2, varscan2
- PTPRS | c.670G>A p.V224M | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759053243, COSV53621128; called by muse, mutect2, varscan2
- PUS1 | c.361G>A p.V121I | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.039); catalogued as rs770785029, COSV59036252; called by muse, mutect2
- PXDNL | c.55C>A p.L19M | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.598); catalogued as COSV62495617; called by muse, mutect2, varscan2
- QKI | c.229G>T p.G77* | Nonsense Mutation (SNP) | VAF 19/121 reads (16%) | catalogued as COSV51698720, COSV99275803; called by muse, mutect2, varscan2
- RANBP17 | c.1922del p.N641Tfs*35 | Frame Shift Del (DEL) | VAF 17/176 reads (10%) | catalogued as rs1339102467; called by mutect2, pindel
- RANBP6 | c.3221G>A p.R1074H | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs143367425; called by muse, mutect2, varscan2
- RANBP9 | c.430_432del p.E144del | In Frame Del (DEL) | VAF 9/44 reads (20%) | catalogued as rs1561701534; called by mutect2, pindel, varscan2
- RAPH1 | c.1862C>A p.A621D | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.307); catalogued as COSV99863660; called by muse, mutect2
- RASAL2 | c.2192T>A p.I731K | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs1285589687; called by muse, mutect2
- RASGRF1 | c.3676C>T p.R1226* | Nonsense Mutation (SNP) | VAF 16/192 reads (8%) | catalogued as rs1457729097, COSV67251376; called by muse, mutect2
- RASGRP2 | c.1492G>A p.V498I | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV62451150; called by muse, mutect2, varscan2
- RB1CC1 | c.4274C>T p.A1425V | Missense Mutation (SNP) | VAF 8/135 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99212176; called by muse, mutect2
- RBM34 | c.203A>G p.Q68R | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV100784078; called by muse, mutect2, varscan2
- RCVRN | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.14); catalogued as rs754840876, COSV56840987; called by mutect2, varscan2
- RECQL4 | c.3237C>T p.S1079= | Splice Region (SNP) | VAF 11/95 reads (12%) | catalogued as rs770553956; called by muse, mutect2
- RFX8 | c.1630G>A p.V544M (on ENST00000646446; = p.V473M on NM_001145664.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.003); catalogued as rs1220406848; called by muse, mutect2
- RHOBTB1 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100558314; called by muse, mutect2, varscan2
- RNF152 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT tolerated (0.71); PolyPhen benign (0.024); catalogued as rs565129525, COSV57185003; called by muse, mutect2, varscan2
- ROCK1 | c.3921del p.K1307Nfs*3 | Frame Shift Del (DEL) | VAF 42/159 reads (26%) | catalogued as rs752898741; called by mutect2, varscan2
- RPGRIP1L | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs886042345, COSV50902701; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RPUSD3 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs748220786, COSV59614056; called by muse, mutect2
- RRP12 | c.3304C>T p.R1102* | Nonsense Mutation (SNP) | VAF 6/74 reads (8%) | catalogued as rs1317889263; called by muse, mutect2
- RSAD2 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs753068844; called by muse, mutect2, varscan2
- RTKN | c.194G>A p.R65Q (on ENST00000272430 / NM_001015055.2; = p.R52Q on NM_033046.2) | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1252784104; called by muse, mutect2, varscan2
- RUBCNL | c.1313G>T p.G438V | Missense Mutation (SNP) | VAF 22/238 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100529016; called by muse, mutect2
- SAMD1 | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs747195703, COSV54116614; called by muse, mutect2, varscan2
- SAMD11 | c.476G>A p.S159N | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as COSV100574609; called by muse, mutect2
- SAT1 | c.13G>A p.V5M | Missense Mutation (SNP) | VAF 13/172 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.087); catalogued as COSV63380773; called by muse, mutect2
- SCAMP1 | c.360G>A p.W120* | Nonsense Mutation (SNP) | VAF 7/58 reads (12%) | catalogued as COSV100210422; called by muse, mutect2, varscan2
- SCLT1 | c.1620del p.A541Pfs*3 | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | catalogued as rs760494753; called by mutect2, varscan2
- SCMH1 | c.613C>T p.R205* (on ENST00000326197 / NM_001031694.2; = p.R158* on NM_012236.4) | Nonsense Mutation (SNP) | VAF 20/85 reads (24%) | catalogued as rs1476104286, COSV58239451; called by muse, mutect2, varscan2
- SDCBP2 | c.553C>T p.R185W (on ENST00000339987 / NM_001199784.1; = p.R100W on NM_015685.5) | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1383253202, COSV60590514; called by muse, mutect2
- SEC14L1 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.429); catalogued as rs759470211, COSV66725546; called by muse, mutect2, varscan2
- SEMA4G | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs199762950, COSV99272323; called by muse, mutect2, varscan2
- SEMA6B | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV56703109; called by muse, mutect2, varscan2
- SEPTIN5 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as rs750628669, COSV63530928; called by muse, mutect2, varscan2
- SERPINB7 | c.253dup p.S85Ffs*2 | Frame Shift Ins (INS) | VAF 18/68 reads (26%) | catalogued as rs1434994276; called by pindel, varscan2
- SERPINB7 | c.309del p.F103Lfs*33 | Frame Shift Del (DEL) | VAF 12/108 reads (11%) | catalogued as rs757235730, COSV100321048; called by pindel, varscan2
- SETD2 | c.4003C>T p.R1335C | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs1216047088, COSV57448285; called by muse, mutect2, varscan2
- SH3BP4 | c.1208dup p.N403Kfs*2 | Frame Shift Ins (INS) | VAF 13/78 reads (17%) | catalogued as rs766163019; called by mutect2, pindel, varscan2
- SH3GLB2 | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774874088; called by muse, mutect2, varscan2
- SH3TC1 | c.2287G>A p.A763T | Missense Mutation (SNP) | VAF 16/179 reads (9%) | SIFT tolerated (0.64); PolyPhen benign (0.108); catalogued as rs778847433; called by muse, mutect2
- SHISAL1 | c.377A>G p.D126G | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as rs991173301; called by muse, mutect2, varscan2
- SIN3A | c.1271G>A p.G424D | Missense Mutation (SNP) | VAF 11/148 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); catalogued as rs1229143000, COSV100845127; called by muse, mutect2
- SKIDA1 | c.2300A>G p.E767G | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV71611108; called by muse, mutect2, varscan2
- SKIV2L | c.2483G>A p.R828H | Missense Mutation (SNP) | VAF 17/277 reads (6%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.761); catalogued as rs774644201, COSV61713745; called by muse, mutect2
- SLC17A7 | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.523); catalogued as COSV55549912; called by muse, mutect2
- SLC17A7 | c.676G>A p.G226R | Missense Mutation (SNP) | VAF 23/176 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99676792; called by muse, mutect2, varscan2
- SLC18A2 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1232320075; called by muse, mutect2
- SLC22A10 | c.1195A>G p.T399A | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs1422658324; called by muse, mutect2, varscan2
- SLC22A20P | n.1406G>A | Splice Region (SNP) | VAF 12/49 reads (24%) | catalogued as rs746294579; called by muse, mutect2, varscan2
- SLC23A3 | c.218G>A p.S73N | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV55408996; called by muse, mutect2, varscan2
- SLC5A3 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV62967960; called by muse, mutect2, varscan2
- SLCO4A1 | c.556G>A p.V186M | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.386); catalogued as rs780673329, COSV53893024; called by muse, mutect2
- SMAD3 | c.752C>T p.S251L | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV59290493; called by muse, mutect2, varscan2
- SMARCAD1 | c.1040del p.N347Mfs*24 | Frame Shift Del (DEL) | VAF 16/65 reads (25%) | catalogued as rs754697669; called by mutect2, varscan2
- SMARCB1 | c.557C>T p.T186M (on ENST00000263121; = p.T232M on NM_003073.5) | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.544); catalogued as rs776693680, COSV54093330, COSV54101934; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMC6 | c.641C>T p.T214M | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760703737, COSV61177342; called by muse, mutect2, varscan2
- SMCP | c.320G>T p.S107I | Missense Mutation (SNP) | VAF 12/185 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as COSV100908351; called by muse, mutect2
- SMG6 | c.3152C>T p.S1051L | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs780310601, COSV53970532; called by muse, mutect2, varscan2
- SMTN | c.714del p.S239Afs*118 | Frame Shift Del (DEL) | VAF 7/52 reads (13%) | catalogued as rs747405143; called by mutect2, pindel, varscan2
- SNX29 | c.368T>C p.L123P | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101625440; called by muse, mutect2
- SOX10 | c.778G>A p.G260R | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.581); catalogued as rs367743809; called by muse, mutect2, varscan2
- SOX30 | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.043); catalogued as rs1311636995; called by mutect2, varscan2
- SPEM2 | c.1148G>A p.R383H | Missense Mutation (SNP) | VAF 44/194 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.923); catalogued as rs372541199; called by muse, mutect2, varscan2
- SPTB | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1407023521, COSV101071985; called by muse, mutect2, varscan2
- SPTBN2 | c.5950-1G>T p.X1984_splice | Splice Site (SNP) | VAF 4/42 reads (10%) | catalogued as COSV100019064; called by muse, mutect2
- SRCAP | c.6300C>T p.A2100= | Splice Region (SNP) | VAF 10/166 reads (6%) | catalogued as COSV99349943; called by muse, mutect2
- SREK1 | c.914G>A p.R305Q | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1238304081; called by muse, mutect2
- SRRT | c.2250del p.F750Lfs*32 | Frame Shift Del (DEL) | VAF 15/142 reads (11%) | catalogued as COSV99574158; called by mutect2, pindel, varscan2
- SSC4D | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 21/179 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.779); catalogued as COSV51883718; called by muse, mutect2, varscan2
- ST6GAL2 | c.553G>A p.V185M | Missense Mutation (SNP) | VAF 16/88 reads (18%) | PolyPhen benign (0.003); catalogued as rs889490672, COSV64527476; called by muse, mutect2, varscan2
- STAB2 | c.5461-1G>T p.X1821_splice | Splice Site (SNP) | VAF 11/40 reads (28%) | catalogued as COSV66338404; called by muse, mutect2, varscan2
- STIP1 | c.728C>T p.T243I | Missense Mutation (SNP) | VAF 23/323 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.528); catalogued as rs747004405; called by muse, mutect2
- STK32B | c.30del p.V11Cfs*41 | Frame Shift Del (DEL) | VAF 68/289 reads (24%) | catalogued as rs780983138; called by mutect2, pindel, varscan2
- STK40 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs777336899; called by muse, mutect2, varscan2
- STRC | c.3305G>A p.R1102Q | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs768051171, COSV101405414; called by muse, mutect2, varscan2
- SVEP1 | c.2588G>A p.G863D | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV100237830; called by muse, mutect2, varscan2
- SYCP1 | c.2376del p.D793Tfs*65 | Frame Shift Del (DEL) | VAF 26/78 reads (33%) | catalogued as rs745637836; called by mutect2, varscan2
- SYNJ2 | c.1396C>T p.R466* | Nonsense Mutation (SNP) | VAF 31/100 reads (31%) | catalogued as rs766003401; called by muse, mutect2, varscan2
- TAFA1 | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 70/228 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); catalogued as rs769572574, COSV101524442; called by muse, mutect2, varscan2
- TAGAP | c.2059G>T p.G687W | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.533); catalogued as COSV57852812; called by muse, mutect2, varscan2
- TANC2 | c.4556del p.P1519Lfs*33 | Frame Shift Del (DEL) | VAF 22/96 reads (23%) | catalogued as COSV101267456, COSV67333336; called by mutect2, pindel, varscan2
- TAP2 | c.789G>A p.W263* | Nonsense Mutation (SNP) | VAF 18/183 reads (10%) | catalogued as COSV66500661; called by muse, mutect2
- TAP2 | c.628C>T p.R210* | Nonsense Mutation (SNP) | VAF 25/130 reads (19%) | catalogued as rs1372620501, CM100316, COSV66487637; called by muse, mutect2, varscan2
- TARBP2 | c.432dup p.M145Hfs*13 (on ENST00000266987 / NM_134323.2; = p.M124Hfs*13 on NM_004178.4) | Frame Shift Ins (INS) | VAF 12/80 reads (15%) | catalogued as rs750181498; called by mutect2, varscan2
- TCF12 | c.1243C>T p.R415W | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs771571672, COSV51004691; called by muse, varscan2
- TDRD3 | c.1949G>A p.R650Q | Missense Mutation (SNP) | VAF 5/113 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs921322836; called by muse, mutect2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 20/86 reads (23%) | catalogued as rs763321097; called by mutect2, varscan2
- TENM4 | c.6966G>T p.K2322N | Missense Mutation (SNP) | VAF 47/220 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV53657883; called by muse, mutect2, varscan2
- TENT5B | c.620C>G p.S207W | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56693439, COSV56693637; called by muse, mutect2, varscan2
- TEX13B | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs202053690; called by muse, mutect2, varscan2
- TGM7 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.709); catalogued as rs762583560, COSV101476845; called by muse, mutect2, varscan2
- THAP3 | c.656G>A p.R219H (on ENST00000054650 / NM_001195753.1; = p.R218H on NM_001195752.1) | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.683); catalogued as rs774544046, COSV50011513; called by muse, mutect2, varscan2
- THSD7A | c.3799-1G>A p.X1267_splice | Splice Site (SNP) | VAF 11/41 reads (27%) | catalogued as COSV101439745; called by muse, mutect2, varscan2
- TLCD3B | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.037); catalogued as COSV99662389; called by muse, mutect2
- TMEM196 | c.192del p.K64Nfs*6 | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | catalogued as rs759398828; called by mutect2, varscan2
- TMEM225 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV66693427; called by muse, mutect2, varscan2
- TMEM229B | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 18/262 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100664300; called by muse, mutect2
- TMEM39A | c.1069C>T p.Q357* | Nonsense Mutation (SNP) | VAF 12/208 reads (6%) | catalogued as COSV59901265; called by muse, mutect2
- TMEM52B | c.26C>T p.A9V (on ENST00000381923 / NM_001079815.1; = p.R4W on NM_153022.4) | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs768022750, COSV53728918; called by muse, mutect2, varscan2
- TMEM60 | c.231del p.A78Pfs*11 | Frame Shift Del (DEL) | VAF 12/60 reads (20%) | catalogued as rs749773249; called by mutect2, varscan2
- TNC | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as rs975002183, COSV60791684; called by muse, mutect2, varscan2
- TNN | c.3596-2_3596-1insT p.X1199_splice | Splice Site (INS) | VAF 23/95 reads (24%) | catalogued as COSV99511757; called by mutect2, pindel, varscan2
- TOMM70 | c.1627A>G p.K543E | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV52524509; called by muse, mutect2, varscan2
- TOPAZ1 | c.1893del p.A632Lfs*5 | Frame Shift Del (DEL) | VAF 14/59 reads (24%) | catalogued as rs753884819, COSV59073348; called by mutect2, varscan2
- TPTE | c.856+2T>C p.X286_splice (on ENST00000618007 / NM_199261.4; = p.X268_splice on NM_199259.4) | Splice Site (SNP) | VAF 14/226 reads (6%) | catalogued as rs1204103867; called by muse, mutect2
- TRAK1 | c.2239C>T p.R747W | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs376571547; called by muse, mutect2, varscan2
- TRIM37 | c.1594G>A p.D532N | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.627); catalogued as rs1229223424; called by muse, mutect2, varscan2
- TRIM4 | c.1450del p.W484Gfs*2 | Frame Shift Del (DEL) | VAF 12/64 reads (19%) | catalogued as rs1254691563; ClinVar: not provided; called by mutect2, pindel, varscan2
- TRIM42 | c.1183A>G p.M395V | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1380618403; called by muse, mutect2
- TRIM47 | c.1648G>C p.V550L | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV54668463, COSV54669211; called by muse, mutect2, varscan2
- TRIM51 | c.430del p.M144Cfs*15 | Frame Shift Del (DEL) | VAF 34/241 reads (14%) | catalogued as rs763121810; called by mutect2, varscan2
- TRPC3 | c.409A>G p.T137A (on ENST00000379645 / NM_001366479.2; = p.T64A on NM_003305.2) | Missense Mutation (SNP) | VAF 33/216 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.403); catalogued as COSV53372632; called by muse, mutect2, varscan2
- TSHZ2 | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs772219519, COSV61586704, COSV61591051; called by muse, mutect2, varscan2
- TTI2 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.219); catalogued as COSV100659689; called by muse, mutect2
- TTN | c.93238G>A p.V31080I (on ENST00000591111; = p.V23656I on NM_003319.4) | Missense Mutation (SNP) | VAF 11/113 reads (10%) | PolyPhen possibly damaging (0.528); catalogued as rs533651182, COSV60034958; ClinVar: uncertain significance; called by muse, mutect2
- TTN | c.77610G>T p.K25870N (on ENST00000591111; = p.K18446N on NM_003319.4) | Missense Mutation (SNP) | VAF 28/228 reads (12%) | PolyPhen benign (0.015); catalogued as COSV60403323; called by muse, mutect2, varscan2
- TTN | c.13582G>A p.D4528N (on ENST00000591111; = p.D3601N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/117 reads (25%) | PolyPhen benign (0.014); catalogued as rs373378672; ClinVar: benign / uncertain significance / likely benign; called by muse, mutect2, varscan2
- TUBB4B | c.856G>A p.V286M | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV61115519; called by muse, mutect2, varscan2
- TULP2 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV54387447; called by muse, mutect2, varscan2
- TUT7 | c.1789G>T p.D597Y | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99463314; called by muse, mutect2, varscan2
- TVP23A | c.420del p.F140Lfs*7 | Frame Shift Del (DEL) | VAF 35/86 reads (41%) | catalogued as rs760251146; called by mutect2, varscan2
- U2AF1L4 | c.466C>T p.R156C (on ENST00000412391; = p.R117C on NM_001040425.3) | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs770561205, COSV99494940; called by muse, mutect2, varscan2
- UBB | c.65C>T p.T22I | Missense Mutation (SNP) | VAF 83/250 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as COSV56219534; called by muse, mutect2
- UBE4B | c.2323C>T p.R775C (on ENST00000343090 / NM_001105562.3; = p.R646C on NM_006048.5) | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53534906; called by muse, mutect2, varscan2
- UNCX | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60333503; called by muse, mutect2, varscan2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 15/47 reads (32%) | catalogued as rs767420916; called by mutect2, varscan2
- UPK3B | c.647G>A p.R216Q (on ENST00000257632; = p.D188N on NM_001347684.2) | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as rs758702310, COSV57537069; called by muse, mutect2, varscan2
- USF3 | c.439del p.I147Lfs*22 | Frame Shift Del (DEL) | VAF 12/59 reads (20%) | catalogued as rs747493460; called by mutect2, varscan2
- USH2A | c.701A>G p.H234R | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as COSV100228066; called by muse, mutect2
- USP6 | c.449C>T p.T150M | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs546022036, COSV51492477; called by muse, mutect2, varscan2
- VANGL2 | c.662C>T p.S221L | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63604512; called by muse, mutect2, varscan2
- VAPB | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 22/295 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs892724485, COSV99668541; called by muse, mutect2
- VARS1 | c.1816C>T p.R606W | Missense Mutation (SNP) | VAF 15/149 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761390538, COSV63304368; called by muse, mutect2
- WDFY4 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as rs765608663; called by muse, mutect2, varscan2
- WDR7 | c.4460G>A p.R1487H | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1173067468; called by muse, mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 38/119 reads (32%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WDTC1 | c.1090C>T p.R364C (on ENST00000319394 / NM_001276252.2; = p.R363C on NM_015023.5) | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.471); catalogued as rs775108929; called by muse, mutect2, varscan2
- WNT4 | c.125C>T p.T42M | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.759); catalogued as rs1453786532, COSV51604810; called by muse, mutect2, varscan2
- WRAP53 | c.1565del p.A522Gfs*26 | Frame Shift Del (DEL) | VAF 12/81 reads (15%) | catalogued as rs373064567, COSV56832921, COSV56833408; called by mutect2, pindel, varscan2
- WWP2 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0.226); catalogued as rs1029698891, COSV63125349; called by muse, mutect2
- XCR1 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 65/202 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs745583108, COSV58571053; called by muse, mutect2, varscan2
- XPO7 | c.2854C>T p.R952C | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV53018764; called by muse, mutect2, varscan2
- YBX2 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs752018878; called by muse, mutect2, varscan2
- Z83844.2 | c.1414T>C p.S472P | Missense Mutation (SNP) | VAF 43/192 reads (22%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs771125702; called by muse, mutect2, varscan2
- ZBED5 | c.712del p.I238* | Frame Shift Del (DEL) | VAF 24/73 reads (33%) | catalogued as COSV69721336; called by mutect2, pindel, varscan2
- ZDHHC5 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV99762643; called by muse, mutect2, varscan2
- ZFHX3 | c.7667C>T p.A2556V | Missense Mutation (SNP) | VAF 57/163 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs147043604; called by muse, mutect2, varscan2
- ZFP36 | c.988_989del p.V330Ffs*2 (on ENST00000594442; = p.V324Ffs*2 on NM_003407.5) | Frame Shift Del (DEL) | VAF 8/21 reads (38%) | catalogued as rs1568383645; called by mutect2, varscan2
- ZFX | c.2329C>T p.R777W | Missense Mutation (SNP) | VAF 72/200 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1486637918, COSV100458235; called by muse, mutect2, varscan2
- ZNF141 | c.1162del p.I388Ffs*51 | Frame Shift Del (DEL) | VAF 10/102 reads (10%) | catalogued as rs782618581; called by mutect2, pindel, varscan2
- ZNF142 | c.5273G>A p.R1758Q (on ENST00000411696 / NM_001379660.1; = p.R1558Q on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.181); catalogued as rs757596506, COSV68745041; called by muse, mutect2
- ZNF337 | c.979C>T p.R327* | Nonsense Mutation (SNP) | VAF 16/90 reads (18%) | catalogued as rs564453457, COSV53320583; called by muse, mutect2, varscan2
- ZNF462 | c.3502del p.R1168Gfs*9 | Frame Shift Del (DEL) | VAF 21/65 reads (32%) | catalogued as COSV52934861; called by mutect2, pindel, varscan2
- ZNF512B | c.737T>C p.M246T | Missense Mutation (SNP) | VAF 136/446 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs1456673337; called by muse, varscan2
- ZNF516 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as rs371922179; called by muse, mutect2
- ZNF517 | c.1456C>T p.R486W | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as rs1341380619, COSV63464758; called by muse, mutect2
- ZNF605 | c.1520G>A p.C507Y | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100053530; called by muse, mutect2, varscan2
- ZNF765 | c.1433C>T p.T478M | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs201583297; called by muse, mutect2, varscan2
- ZNF793 | c.1013C>T p.P338L | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as rs375572663, COSV71324935; called by muse, mutect2, varscan2
- ZNFX1 | c.2870G>A p.R957H | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.42); catalogued as rs562054265, COSV65574663; called by muse, mutect2, varscan2
- ZRSR2 | c.643A>G p.R215G | Missense Mutation (SNP) | VAF 86/214 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs1037092451; called by muse, mutect2, varscan2
- ABCB1 | c.349T>C p.Y117H | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ABCC8 | c.957C>A p.C319* | Nonsense Mutation (SNP) | VAF 14/76 reads (18%) | called by muse, mutect2, varscan2
- ABL2 | c.1478A>C p.Q493P (on ENST00000502732 / NM_007314.4; = p.Q478P on NM_005158.5) | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- ACACA | c.2029G>C p.A677P | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- ACE | c.938T>C p.L313P | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- ADAMTS17 | c.514C>A p.P172T | Missense Mutation (SNP) | VAF 37/152 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- ADAMTS6 | c.2853del p.E952Sfs*89 | Frame Shift Del (DEL) | VAF 8/80 reads (10%) | called by mutect2, pindel
- ADAMTSL4 | c.3124C>A p.L1042M | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.557); called by muse, mutect2
- ADCY9 | c.444del p.A149Rfs*38 | Frame Shift Del (DEL) | VAF 12/134 reads (9%) | called by mutect2, pindel
- ADGRV1 | c.14022G>T p.K4674N | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ADRA2B | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 84/369 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- AHNAK2 | c.13342dup p.D4448Gfs*6 | Frame Shift Ins (INS) | VAF 21/121 reads (17%) | called by mutect2, pindel, varscan2
- AKAP11 | c.1610dup p.N537Kfs*2 | Frame Shift Ins (INS) | VAF 14/65 reads (22%) | called by mutect2, varscan2
- AKAP11 | c.4820del p.F1607Sfs*48 | Frame Shift Del (DEL) | VAF 10/100 reads (10%) | called by mutect2, pindel
- AKAP6 | c.5613G>C p.E1871D | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AKAP9 | c.3608del p.L1203Yfs*16 | Frame Shift Del (DEL) | VAF 21/98 reads (21%) | called by mutect2, pindel, varscan2
- AMD1 | c.43G>T p.E15* | Nonsense Mutation (SNP) | VAF 21/56 reads (38%) | called by muse, mutect2, varscan2
- ANKRD11 | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ANO2 | c.1775T>G p.L592R (on ENST00000356134 / NM_001278597.3; = p.L596R on NM_001278596.3) | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ANTXR2 | c.1069_1070del p.A357Pfs*14 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | called by mutect2, pindel, varscan2
- AP1G1 | c.2122A>G p.T708A | Missense Mutation (SNP) | VAF 24/215 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- AP2A1 | c.492del p.K165Sfs*69 | Frame Shift Del (DEL) | VAF 13/56 reads (23%) | called by mutect2, pindel, varscan2
- APOL6 | c.385A>G p.T129A | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ARHGAP11A | c.1884dup p.L629Ifs*3 | Frame Shift Ins (INS) | VAF 27/142 reads (19%) | called by mutect2, pindel, varscan2
- ARHGEF4 | c.889C>T p.R297W | Missense Mutation (SNP) | VAF 22/245 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARMH1 | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 56/223 reads (25%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- ARNTL2 | c.893G>T p.G298V | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2
- ASCL4 | c.109del p.L37Sfs*53 | Frame Shift Del (DEL) | VAF 16/76 reads (21%) | called by mutect2, varscan2
- ASTN1 | c.2681C>T p.P894L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ATF6 | c.242G>A p.C81Y | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ATP13A4 | c.281T>G p.L94R | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- ATP13A5 | c.2953T>C p.C985R | Missense Mutation (SNP) | VAF 77/348 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- ATP1A4 | c.196G>T p.D66Y | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- ATP4A | c.635C>T p.A212V | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ATXN2L | c.2374C>T p.P792S | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BEX1 | c.302T>C p.L101S | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- BIRC5 | c.38T>C p.F13S | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- BTBD6 | c.583A>T p.S195C | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C10orf71 | c.3971del p.P1324Hfs*20 | Frame Shift Del (DEL) | VAF 12/77 reads (16%) | called by mutect2, pindel, varscan2
- C14orf93 | c.1028del p.K343Sfs*7 | Frame Shift Del (DEL) | VAF 8/84 reads (10%) | called by mutect2, varscan2
- C16orf91 | c.234G>T p.K78N | Missense Mutation (SNP) | VAF 57/164 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- C1QBP | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- C2orf73 | c.855del p.K285Nfs*17 | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | called by mutect2, pindel, varscan2
- C3 | c.3665A>G p.D1222G | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CACTIN | c.2072C>T p.T691M | Missense Mutation (SNP) | VAF 95/303 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAST | c.238A>G p.N80D (on ENST00000341926; = p.N163D on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 99/340 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CATSPER3 | c.322A>G p.N108D | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC171 | c.955_957del p.K319del | In Frame Del (DEL) | VAF 21/65 reads (32%) | called by mutect2, pindel, varscan2
- CCDC28B | c.209G>A p.S70N | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CD101 | c.2074A>T p.N692Y | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); called by muse, mutect2
- CD248 | c.2229del p.R744Gfs*61 | Frame Shift Del (DEL) | VAF 17/84 reads (20%) | called by mutect2, pindel, varscan2
- CDC23 | c.413T>C p.L138S | Missense Mutation (SNP) | VAF 55/202 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- CDH8 | c.286dup p.I96Nfs*8 | Frame Shift Ins (INS) | VAF 18/79 reads (23%) | called by mutect2, varscan2
- CELF4 | c.1013T>C p.V338A | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- CENPC | c.406del p.I136Yfs*6 | Frame Shift Del (DEL) | VAF 18/162 reads (11%) | called by mutect2, pindel, varscan2
- CEP170 | c.611del p.N204Tfs*11 | Frame Shift Del (DEL) | VAF 7/35 reads (20%) | called by mutect2, pindel, varscan2
- CETP | c.366G>A p.W122* | Nonsense Mutation (SNP) | VAF 56/155 reads (36%) | called by muse, mutect2, varscan2
- CFAP46 | c.4089del p.E1364Rfs*56 | Frame Shift Del (DEL) | VAF 17/68 reads (25%) | called by mutect2, pindel, varscan2
- CFDP1 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- CFHR5 | c.901T>C p.Y301H | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- CHAF1A | c.2189G>T p.R730M | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); called by muse, mutect2
- CHD8 | c.2078G>T p.R693M (on ENST00000646647 / NM_001170629.2; = p.R414M on NM_020920.4) | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- CLASP1 | c.3392G>A p.S1131N | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- CNST | c.388del p.S130Qfs*7 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | called by mutect2, pindel, varscan2
- COL11A2 | c.3122dup p.G1042Wfs*11 (on ENST00000341947 / NM_080680.3; = p.G935Wfs*11 on NM_080679.2) | Frame Shift Ins (INS) | VAF 9/95 reads (9%) | called by mutect2, pindel, varscan2
- COL12A1 | c.1892C>A p.A631D | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- COL6A1 | c.1744C>T p.P582S | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CSMD1 | c.3043G>T p.G1015* (on ENST00000520002; = p.G1014* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 36/116 reads (31%) | called by muse, mutect2, varscan2
- CSMD3 | c.5432T>C p.L1811P (on ENST00000297405 / NM_001363185.1; = p.L1707P on NM_052900.3) | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- CSMD3 | c.49T>A p.W17R | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- CTBP2 | c.1118A>C p.Q373P | Missense Mutation (SNP) | VAF 44/169 reads (26%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CUL9 | c.4772C>T p.T1591I | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CX3CR1 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DAB1 | c.1286C>T p.S429F (on ENST00000371231; = p.S396F on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- DDN | c.1013C>T p.T338I | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.015); called by muse, mutect2
- DGKD | c.3074G>A p.G1025D (on ENST00000264057 / NM_152879.3; = p.G981D on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- DHODH | c.332G>A p.G111D | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DHX38 | c.1955A>C p.D652A | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DKK2 | c.128G>A p.G43D | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- DLG2 | c.1953T>A p.S651R | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- DLGAP4 | c.2654G>A p.W885* (on ENST00000339266 / NM_001365621.1; = p.W882* on NM_014902.6) | Nonsense Mutation (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- DMRT3 | c.775T>C p.F259L | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DMXL1 | c.3079C>T p.P1027S | Missense Mutation (SNP) | VAF 19/273 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.724); called by muse, mutect2
- DNAH11 | c.3750dup p.C1251Mfs*5 | Frame Shift Ins (INS) | VAF 13/36 reads (36%) | called by mutect2, pindel, varscan2
- DNAH6 | c.11470C>A p.L3824I | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- DNAH9 | c.8524A>G p.S2842G | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- DNAJA3 | c.248del p.F83Sfs*16 | Frame Shift Del (DEL) | VAF 18/78 reads (23%) | called by mutect2, pindel, varscan2
- DNAJB1 | c.982dup p.Q328Pfs*8 | Frame Shift Ins (INS) | VAF 30/130 reads (23%) | called by mutect2, pindel, varscan2
- DNHD1 | c.4072del p.R1358Afs*11 | Frame Shift Del (DEL) | VAF 23/154 reads (15%) | called by mutect2, pindel, varscan2
- DOCK1 | c.5066A>G p.D1689G | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.146); called by muse, mutect2
- DOCK6 | c.3382G>T p.A1128S | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.031); called by muse, mutect2
- DOCK7 | c.3941G>A p.G1314D (on ENST00000635253 / NM_001367561.1; = p.G1283D on NM_033407.3) | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- DOK5 | c.340A>G p.T114A | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- EAF2 | c.243dup p.P82Tfs*11 | Frame Shift Ins (INS) | VAF 26/104 reads (25%) | called by mutect2, varscan2
- EEF2 | c.104T>C p.L35P | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EFCAB7 | c.1293del p.F431Lfs*3 | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | called by mutect2, pindel, varscan2
- EFCAB8 | c.2826dup p.T943Hfs*12 | Frame Shift Ins (INS) | VAF 26/246 reads (11%) | called by mutect2, pindel
- EGR2 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EHD2 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- EIF2B3 | c.31G>T p.G11C | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ELAVL4 | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 16/223 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.411); called by muse, mutect2
- ELP1 | c.1052G>T p.W351L | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EP400 | c.6275C>A p.P2092Q | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.029); called by muse, mutect2
- EPHA8 | c.786C>G p.C262W | Missense Mutation (SNP) | VAF 69/208 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EPHB1 | c.2542G>A p.D848N | Missense Mutation (SNP) | VAF 64/233 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ERO1A | c.761T>C p.L254P | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ESPN | c.1292del p.P431Hfs*32 | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | called by mutect2, pindel
- ESRRB | c.484A>G p.K162E | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); called by muse, mutect2
- EYA2 | c.1474G>A p.G492S | Missense Mutation (SNP) | VAF 43/248 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM120B | c.2257T>C p.S753P | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- FAM131C | c.463C>A p.Q155K | Missense Mutation (SNP) | VAF 46/191 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- FAM161B | c.921dup p.I308Dfs*38 (on ENST00000651776; = p.I245Dfs*38 on NM_152445.3) | Frame Shift Ins (INS) | VAF 12/100 reads (12%) | called by pindel, varscan2
- FAM168B | c.517del p.H173Tfs*63 | Frame Shift Del (DEL) | VAF 25/209 reads (12%) | called by mutect2, pindel, varscan2
- FAM186A | c.2705A>C p.E902A | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- FAM214B | c.1002del p.S335Vfs*77 | Frame Shift Del (DEL) | VAF 17/70 reads (24%) | called by mutect2, pindel, varscan2
- FAM47E | c.1088del p.G363Afs*26 | Frame Shift Del (DEL) | VAF 9/64 reads (14%) | called by mutect2, pindel, varscan2
- FANCL | c.506T>G p.F169C | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- FBXO15 | c.696del p.K232Nfs*5 | Frame Shift Del (DEL) | VAF 25/150 reads (17%) | called by mutect2, pindel, varscan2
- FBXW10 | c.1539A>T p.R513S | Missense Mutation (SNP) | VAF 82/306 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- FCGBP | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.857); called by muse, mutect2
- FLRT1 | c.1481T>C p.L494P | Missense Mutation (SNP) | VAF 11/166 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FOXD3 | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.019); called by muse, mutect2
- FRK | c.611T>G p.L204R | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GABBR1 | c.2691A>T p.E897D | Missense Mutation (SNP) | VAF 33/180 reads (18%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- GAL3ST4 | c.1278del p.F427Sfs*17 | Frame Shift Del (DEL) | VAF 61/214 reads (29%) | called by mutect2, pindel, varscan2
- GALNT7 | c.751A>C p.K251Q | Missense Mutation (SNP) | VAF 10/129 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- GCLC | c.1286G>A p.R429Q (on ENST00000643939; = p.R427Q on NM_001498.4) | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- GEM | c.311G>A p.S104N | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GFPT2 | c.1351G>A p.V451M | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- GIGYF1 | c.2707A>G p.T903A | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- GPATCH8 | c.1759A>T p.K587* | Nonsense Mutation (SNP) | VAF 27/82 reads (33%) | called by muse, mutect2, varscan2
- GPBP1L1 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GPNMB | c.1147dup p.I383Nfs*9 (on ENST00000381990 / NM_001005340.2; = p.I371Nfs*9 on NM_002510.3) | Frame Shift Ins (INS) | VAF 11/60 reads (18%) | called by mutect2, pindel, varscan2
- GPR82 | c.325A>T p.I109F | Missense Mutation (SNP) | VAF 37/54 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- GREB1 | c.1133G>A p.C378Y | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- GRID2IP | c.3260C>T p.T1087I | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- GYG2P1 | n.189C>T | Splice Region (SNP) | VAF 16/87 reads (18%) | called by muse, varscan2
- HACD2 | c.764A>G p.*255Wext*33 | Nonstop Mutation (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
- HCN2 | c.1325G>A p.W442* | Nonsense Mutation (SNP) | VAF 26/93 reads (28%) | called by muse, mutect2, varscan2
- HDLBP | c.1651dup p.S551Kfs*2 | Frame Shift Ins (INS) | VAF 14/124 reads (11%) | called by mutect2, pindel
- HECTD3 | c.635del p.P212Rfs*11 | Frame Shift Del (DEL) | VAF 10/75 reads (13%) | called by mutect2, pindel, varscan2
- HEPHL1 | c.2669T>C p.V890A | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- HERC2 | c.4378G>A p.A1460T | Missense Mutation (SNP) | VAF 53/440 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- HERC2 | c.586G>C p.G196R | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HIVEP2 | c.2636G>T p.R879M | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- HNRNPD | c.144_149del p.G49_G50del | In Frame Del (DEL) | VAF 8/41 reads (20%) | called by mutect2, varscan2
- HNRNPF | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- HP1BP3 | c.394del p.T132Qfs*13 | Frame Shift Del (DEL) | VAF 17/83 reads (20%) | called by mutect2, pindel, varscan2
- HSP90AA1 | c.687A>T p.E229D | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.921); called by muse, varscan2
- HUWE1 | c.8941C>T p.R2981C | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HYAL2 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- IGF2R | c.4713G>C p.R1571S | Missense Mutation (SNP) | VAF 64/208 reads (31%) | SIFT tolerated (0.7); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- IGSF11 | c.1025G>A p.G342D (on ENST00000393775 / NM_001015887.3; = p.G341D on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/157 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- IGSF6 | c.67G>T p.G23C | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IL17RC | c.1441T>G p.C481G (on ENST00000295981 / NM_153461.4; = p.C395G on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- IL7R | c.263T>C p.L88P | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.042); called by muse, mutect2
- ING5 | c.234C>A p.Y78* | Nonsense Mutation (SNP) | VAF 66/301 reads (22%) | called by muse, mutect2, varscan2
- INPP4A | c.2879C>T p.A960V (on ENST00000074304 / NM_001134224.1; = p.A921V on NM_004027.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- IRX2 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.215); called by muse, mutect2
- IRX4 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, varscan2
- ITPRIP | c.785T>C p.L262P | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- JHY | c.2162T>C p.I721T | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNA3 | c.1366G>T p.G456W | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT tolerated (0.27); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNE4 | c.425C>T p.S142L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- KCNQ5 | c.875A>C p.N292T | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- KCTD19 | c.66G>A p.W22* | Nonsense Mutation (SNP) | VAF 25/89 reads (28%) | called by muse, mutect2, varscan2
- KDM4D | c.131A>C p.H44P | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA0825 | c.2301del p.F767Lfs*27 | Frame Shift Del (DEL) | VAF 43/188 reads (23%) | called by pindel, varscan2
- KIAA2026 | c.3296T>A p.I1099N | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- KIAA2026 | c.1196T>C p.L399S | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KIDINS220 | c.4203del p.S1403Lfs*29 | Frame Shift Del (DEL) | VAF 15/121 reads (12%) | called by mutect2, pindel, varscan2
- KIF13B | c.2623C>A p.L875M | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- KIFBP | c.1516del p.I506* | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | called by mutect2, varscan2
- KLHDC9 | c.77T>G p.L26W | Missense Mutation (SNP) | VAF 61/190 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- KPNA3 | c.1324G>A p.A442T | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LAMA1 | c.5771A>G p.H1924R | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- LCE3D | c.152G>T p.G51V | Missense Mutation (SNP) | VAF 44/176 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.666); called by muse, mutect2
- LMTK3 | c.1987C>T p.R663C | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- LONRF2 | c.785C>A p.P262H | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LPCAT4 | c.1148C>T p.T383I | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LRIT1 | c.724G>T p.A242S | Missense Mutation (SNP) | VAF 10/135 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.018); called by muse, mutect2
- LRRC14 | c.1333T>C p.S445P | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LRRC18 | c.89del p.K30Sfs*5 | Frame Shift Del (DEL) | VAF 11/76 reads (14%) | called by mutect2, pindel, varscan2
- LRRC37A2 | c.3905del p.R1302Kfs*13 | Frame Shift Del (DEL) | VAF 16/142 reads (11%) | called by mutect2, varscan2
- LRRC74B | c.310A>G p.S104G | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- LRRN3 | c.1785T>G p.I595M | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.235); called by muse, mutect2
- LTN1 | c.1967del p.N656Ifs*11 | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | called by mutect2, pindel, varscan2
- LYST | c.6023T>C p.L2008S | Missense Mutation (SNP) | VAF 52/180 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAP1A | c.5311C>T p.R1771C | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- MAP1S | c.593del p.P198Rfs*93 | Frame Shift Del (DEL) | VAF 14/68 reads (21%) | called by pindel, varscan2
- MAP2 | c.1053del p.K351Nfs*38 | Frame Shift Del (DEL) | VAF 14/60 reads (23%) | called by mutect2, pindel, varscan2
- MAP2K2 | c.95C>A p.A32E | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- MARCHF2 | c.484G>A p.G162R | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
560 further variants in this file (194 protein-altering or splice-affecting, 262 silent, 104 other) are not listed here.
